Somatic mutation profile of tumor specimen ALCH-B1V3-TTP1-A (aliquot ALCH-B1V3-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1V3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 82.4 years (30,088 days).
Specimen ALCH-B1V3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 157a5bb1-43eb-430e-9db2-e2383862dac3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1V3-NB1-A (Blood Derived Normal), aliquot ALCH-B1V3-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2da2e5b1-39aa-470b-9467-817f667c0881

The open-access MAF lists 252 somatic variants for this specimen: 176 protein-altering or splice-affecting, 55 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, Silent 55, Nonsense Mutation 16, Intron 7, RNA 5, Frame Shift Del 4, Splice Site 4, 3'Flank 3, Frame Shift Ins 3, 3'UTR 2, Translation Start Site 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 31/408 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2
- ABCC1 | c.1218G>T p.K406N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60686824; called by muse, mutect2, varscan2
- ADAM30 | c.530A>T p.D177V | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV65561080; called by muse, mutect2, varscan2
- ADAM7 | c.2007C>G p.I669M | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV51542547; called by muse, mutect2
- AK7 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV50876788; called by muse, mutect2
- AKR1C8P | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as rs782655097; called by muse, mutect2, varscan2
- APLP1 | c.1163G>T p.R388L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV55707182; called by muse, mutect2, varscan2
- ASIC2 | c.289T>C p.F97L | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.067); catalogued as COSV63295687; called by muse, mutect2
- BCL2L14 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769850390, COSV53791877; called by muse, mutect2, varscan2
- BRINP3 | c.1314C>A p.F438L | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs769445823, COSV66535791; called by muse, mutect2, varscan2
- CABS1 | c.81del p.F28Lfs*24 | Frame Shift Del (DEL) | VAF 18/183 reads (10%) | catalogued as COSV99909218; called by mutect2, pindel, varscan2
- CCL1 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV56774429; called by muse, mutect2, varscan2
- CDH1 | c.67C>G p.Q23E | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55726950; called by mutect2, varscan2
- CNTNAP2 | c.3724G>A p.D1242N | Missense Mutation (SNP) | VAF 43/398 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV62189275; called by muse, mutect2, varscan2
- CSMD1 | c.9236G>T p.R3079L (on ENST00000520002; = p.R3078L on NM_033225.6) | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs181332761; called by muse, mutect2, varscan2
- CSMD3 | c.7221G>T p.L2407F (on ENST00000297405 / NM_001363185.1; = p.L2303F on NM_052900.3) | Missense Mutation (SNP) | VAF 28/480 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV52160099; called by muse, mutect2
- CXCR1 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV55283029; called by muse, mutect2, varscan2
- DCDC1 | c.4149C>G p.Y1383* (on ENST00000597505 / NM_001367979.1; = p.Y490* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 32/215 reads (15%) | catalogued as COSV58004209; called by muse, mutect2, varscan2
- DMP1 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV56822577; called by muse, mutect2, varscan2
- DYSF | c.3845C>A p.P1282Q | Missense Mutation (SNP) | VAF 59/276 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV50451927; called by muse, mutect2, varscan2
- ELFN1 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201617876; called by muse, mutect2, varscan2
- F11 | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as CM105315, COSV53005768; called by muse, mutect2, varscan2
- FRYL | c.3323C>T p.A1108V | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs775967535, COSV51954587; called by muse, mutect2
- GNAS | c.1433C>A p.A478E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.557); catalogued as COSV58328077; called by muse, varscan2
- GPR65 | c.400G>T p.V134F | Missense Mutation (SNP) | VAF 31/331 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99966085; called by muse, mutect2, varscan2
- GPT | c.1399del p.R467Gfs*2 | Frame Shift Del (DEL) | VAF 15/137 reads (11%) | catalogued as COSV52954369; called by mutect2, pindel, varscan2
- HGF | c.1328C>A p.P443Q | Missense Mutation (SNP) | VAF 43/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55945553; called by muse, mutect2, varscan2
- ITGA2B | c.829G>T p.G277W | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV52231876; called by muse, mutect2, varscan2
- KCNJ16 | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as COSV52251463, COSV52253313; called by muse, mutect2
- KCNJ8 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.488); catalogued as rs750317966, COSV99557389; called by muse, mutect2
- KEAP1 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50430694; called by muse, mutect2, varscan2
- KIF25 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs545392392; called by muse, mutect2, varscan2
- KRIT1 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 76/518 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs778621203; called by muse, mutect2, varscan2
- MAGI1 | c.1927A>G p.T643A | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1396930439; called by muse, mutect2
- MTRNR2L5 | c.51C>G p.D17E | Missense Mutation (SNP) | VAF 11/166 reads (7%) | PolyPhen possibly damaging (0.631); catalogued as COSV64529396; called by muse, mutect2
- MYBL2 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV99406736; called by muse, mutect2, varscan2
- NCBP3 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50106896; called by muse, mutect2, varscan2
- NRXN1 | c.253C>A p.R85S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as COSV68029352; called by muse, mutect2, varscan2
- NRXN3 | c.1729G>T p.E577* (on ENST00000335750 / NM_001330195.2; = p.E204* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 11/133 reads (8%) | catalogued as COSV59798386; called by muse, mutect2
- OR56B4 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.12); catalogued as rs772516851, COSV57204811; called by muse, mutect2, varscan2
- OR5D18 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1332591130, COSV100450484; called by muse, mutect2
- OR5R1 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56572183; called by muse, mutect2
- P3R3URF-PIK3R3 | c.58C>A p.R20S | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs560455403; called by muse, mutect2, varscan2
- PCLO | c.14978G>T p.G4993V | Missense Mutation (SNP) | VAF 51/435 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV100427676; called by muse, mutect2, varscan2
- PDCD11 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs779814237, COSV63934336; called by muse, mutect2
- PIM2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs781963527, COSV55946151, COSV55946797; called by muse, mutect2, varscan2
- PMFBP1 | c.755A>T p.Q252L | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.426); catalogued as rs1000105982; called by muse, mutect2, varscan2
- POMT2 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1398447748; called by muse, mutect2, varscan2
- PTHLH | c.492C>A p.D164E | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs747581005; called by muse, mutect2
- PTPRD | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.054); catalogued as rs757922864, COSV61929535; called by muse, mutect2, varscan2
- SEC14L4 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs1011388034; called by muse, mutect2, varscan2
- STK11 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 21/111 reads (19%) | catalogued as COSV58821580, COSV58822105; called by muse, mutect2, varscan2
- THADA | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV57696811; called by muse, mutect2, varscan2
- TLR4 | c.424G>T p.E142* (on ENST00000355622 / NM_138554.5; = p.E102* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 34/169 reads (20%) | catalogued as COSV100790571; called by muse, mutect2, varscan2
- TRRAP | c.10790A>G p.Y3597C (on ENST00000359863 / NM_001244580.1; = p.Y3568C on NM_003496.3) | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62815757; called by muse, mutect2
- U2AF2 | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.764); catalogued as COSV100454029, COSV58276374; called by muse, mutect2, varscan2
- USH2A | c.4945G>T p.G1649* | Nonsense Mutation (SNP) | VAF 77/472 reads (16%) | catalogued as COSV56420015; called by muse, mutect2, varscan2
- WIPF1 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs776761827, COSV55817493, COSV99767885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WNT11 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.438); catalogued as rs1326479514; called by muse, mutect2
- YY1AP1 | c.323G>C p.R108P (on ENST00000295566 / NM_139118.2; = p.R31P on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/427 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs777901819, COSV99804056; called by muse, mutect2, varscan2
- ZNF521 | c.3281C>A p.A1094D | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100832654; called by muse, mutect2, varscan2
- ACSM2B | c.1656G>T p.K552N | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRB3 | c.2131G>T p.A711S | Missense Mutation (SNP) | VAF 29/315 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.675); called by muse, mutect2
- ADSL | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 80/611 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- AHNAK | c.6100G>T p.A2034S | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ARHGEF10L | c.903_906del p.E302Wfs*8 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | called by mutect2, pindel, varscan2
- ARMC9 | c.803G>C p.S268T | Missense Mutation (SNP) | VAF 101/342 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ASMT | c.850A>T p.S284C (on ENST00000381229; = p.S312C on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ATRX | c.7278G>T p.M2426I | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BTN3A3 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- C1orf52 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2
- CALHM4 | c.554C>G p.S185* (on ENST00000368596 / NM_001366078.1; = p.S42* on NM_001256887.3) | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- CATSPERD | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBLN1 | c.385-1G>T p.X129_splice | Splice Site (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2
- CCDC170 | c.2114G>T p.R705M | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- CCT8L2 | c.1265T>C p.M422T | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CHRM2 | c.497dup p.G167Rfs*80 | Frame Shift Ins (INS) | VAF 41/248 reads (17%) | called by mutect2, pindel, varscan2
- CRB2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- CSMD1 | c.1958G>T p.G653V (on ENST00000520002; = p.G652V on NM_033225.6) | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYFIP1 | c.3586A>T p.I1196F | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CYP7B1 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 31/247 reads (13%) | called by muse, mutect2, varscan2
- DIAPH3 | c.1096A>G p.M366V (on ENST00000400324 / NM_001042517.2; = p.M103V on NM_030932.3) | Missense Mutation (SNP) | VAF 18/409 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2
- DISP3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/120 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- DMBX1 | c.149T>A p.L50Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOK6 | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- EFCAB8 | c.2476G>T p.D826Y | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- FAM120B | c.1014G>C p.R338S | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FAM178B | c.1563-1G>T p.X521_splice | Splice Site (SNP) | VAF 31/108 reads (29%) | called by muse, mutect2
- FAM184B | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.403); called by muse, mutect2
- FGFR4 | c.1159G>C p.A387P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- FPR1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2
- FSIP2 | c.2171C>A p.P724H | Missense Mutation (SNP) | VAF 105/457 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRB1 | c.747A>T p.Q249H | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GLIPR1L2 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 13/198 reads (7%) | called by muse, mutect2
- GLYATL2 | c.244C>G p.P82A | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.375); called by muse, mutect2
- HMGCS2 | c.1187+1G>T p.X396_splice | Splice Site (SNP) | VAF 70/305 reads (23%) | called by muse, mutect2, varscan2
- HSF1 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- IGHD | c.217C>G p.P73A | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); called by muse, mutect2
- IGHV1-58 | c.272G>T p.R91M | Missense Mutation (SNP) | VAF 51/348 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- IL31RA | c.1953-2A>G p.X651_splice (on ENST00000354961 / NM_001242638.2; = p.X670_splice on NM_001242637.2) | Splice Site (SNP) | VAF 19/204 reads (9%) | called by muse, mutect2
- INTS10 | c.140_143dup p.I49Hfs*57 | Frame Shift Ins (INS) | VAF 25/142 reads (18%) | called by mutect2, pindel, varscan2
- ITPR2 | c.7501G>T p.G2501W | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JCAD | c.3086G>T p.G1029V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- KALRN | c.8731G>T p.A2911S (on ENST00000360013 / NM_001024660.4; = p.A1214S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KANK1 | c.2144G>T p.R715L | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KARS1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/269 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2
- KCNJ6 | c.652C>A p.L218M | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KCNK9 | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- KIAA0586 | c.3433G>T p.E1145* (on ENST00000619416 / NM_001244190.2; = p.E1084* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 28/248 reads (11%) | called by muse, mutect2, varscan2
- KLHL13 | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KMT2E | c.1697A>T p.Q566L | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- KRTAP19-5 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRTAP20-2 | c.9C>A p.Y3* | Nonsense Mutation (SNP) | VAF 37/198 reads (19%) | called by muse, mutect2, varscan2
- LMNB1 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- LRGUK | c.1444C>G p.L482V | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LRTM2 | c.877T>A p.C293S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.98); called by muse, mutect2
- MALRD1 | c.2090T>G p.L697R | Missense Mutation (SNP) | VAF 13/251 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2
- MALRD1 | c.3902G>T p.R1301L | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MED13 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- MMP26 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO3A | c.4490G>T p.R1497L | Missense Mutation (SNP) | VAF 58/673 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.145); called by muse, mutect2
- MYOM2 | c.2030G>T p.G677V | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAV3 | c.5779G>T p.G1927C (on ENST00000397909 / NM_001024383.2; = p.G1905C on NM_014903.6) | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- NKAIN2 | c.226A>G p.N76D | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- NKX2-4 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLGN3 | c.1533G>T p.Q511H (on ENST00000358741 / NM_181303.2; = p.Q491H on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- NLRP3 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- NLRP6 | c.1694G>A p.C565Y | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.364); called by muse, mutect2
- NRAP | c.584G>T p.R195I | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NRCAM | c.3030G>T p.K1010N (on ENST00000379028 / NM_001371124.1; = p.K994N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.132); called by muse, varscan2
- NRG1 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2
- NUP155 | c.2216C>A p.A739D (on ENST00000231498 / NM_153485.3; = p.A680D on NM_004298.4) | Missense Mutation (SNP) | VAF 46/350 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NUTM2D | c.1336C>A p.Q446K | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OBSCN | c.16610A>T p.Q5537L | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2
- OCA2 | c.1162C>A p.L388M | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR10J5 | c.57C>A p.S19R | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR13G1 | c.658G>T p.V220F | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- OR5L1 | c.833A>T p.Y278F | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR5M1 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR5P3 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR5T1 | c.818G>T p.R273I | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- P3H2 | c.1641G>T p.M547I | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PDE1C | c.79A>T p.T27S | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.55); called by muse, mutect2
- PDE6A | c.906C>A p.Y302* | Nonsense Mutation (SNP) | VAF 23/405 reads (6%) | called by muse, mutect2
- PPP6C | c.349A>G p.R117G | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRSS48 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PSKH2 | c.215del p.G72Afs*9 | Frame Shift Del (DEL) | VAF 11/102 reads (11%) | called by mutect2, pindel, varscan2
- PTPRC | c.3372C>A p.N1124K | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RBM20 | c.2144C>A p.P715H | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RBM46 | c.499G>T p.G167* | Nonsense Mutation (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- RELN | c.3720T>A p.Y1240* | Nonsense Mutation (SNP) | VAF 52/465 reads (11%) | called by muse, mutect2, varscan2
- RFX6 | c.1418T>A p.V473E | Missense Mutation (SNP) | VAF 9/295 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RGSL1 | c.3029C>A p.P1010H | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, varscan2
- RP1L1 | c.3864C>A p.N1288K | Missense Mutation (SNP) | VAF 71/542 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SATL1 | c.470C>A p.A157E (on ENST00000395409; = p.A344E on NM_001012980.2) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SCGB2A1 | c.254A>T p.Y85F | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- SCN9A | c.5725G>T p.V1909F (on ENST00000303354; = p.V1898F on NM_002977.3) | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2
- SERF1A | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 35/371 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- SGCZ | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.262); called by muse, mutect2
- SLC6A15 | c.727A>G p.M243V | Missense Mutation (SNP) | VAF 22/550 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.123); called by muse, mutect2
- TACC1 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2
- TCAF1 | c.2217G>T p.Q739H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- TEAD1 | c.626dup p.S210Lfs*42 | Frame Shift Ins (INS) | VAF 30/310 reads (10%) | called by mutect2, pindel, varscan2
- TFRC | c.2035A>T p.M679L | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMPRSS11B | c.460A>T p.K154* | Nonsense Mutation (SNP) | VAF 24/175 reads (14%) | called by muse, mutect2
- TMSB4Y | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); called by muse, mutect2
- TRAK2 | c.1097A>T p.Y366F | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPC6 | c.2783A>T p.E928V | Missense Mutation (SNP) | VAF 13/269 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); called by muse, mutect2
- TRPC6 | c.2782G>T p.E928* | Nonsense Mutation (SNP) | VAF 13/273 reads (5%) | called by muse, mutect2
- TTLL5 | c.1986G>T p.M662I | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TYRP1 | c.982C>G p.P328A | Missense Mutation (SNP) | VAF 31/315 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UACA | c.2636C>G p.T879S | Missense Mutation (SNP) | VAF 13/309 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.048); called by muse, mutect2
- WSCD2 | c.1608G>T p.Q536H | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.123); called by muse, mutect2
- XYLT1 | c.2307G>T p.M769I | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- YBX1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 15/241 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); called by muse, mutect2
- ZNF727 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKR1A1 | c.264C>A p.P88= | Silent (SNP) | VAF 38/145 reads (26%) | catalogued as COSV100698683; called by muse, mutect2, varscan2
- AP1G1 | c.435C>T p.L145= | Silent (SNP) | VAF 13/216 reads (6%) | called by muse, mutect2
- ASGR2 | c.435C>A p.A145= | Silent (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- ASIC2 | c.597C>A p.G199= | Silent (SNP) | VAF 20/165 reads (12%) | catalogued as COSV56759948; called by muse, mutect2, varscan2
- ATAD2 | c.708T>C p.D236= | Silent (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- BMP2K | c.330C>A p.G110= | Silent (SNP) | VAF 27/304 reads (9%) | called by muse, mutect2
- BOLL | c.606T>A p.S202= | Silent (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2
- CBLIF | c.15C>A p.A5= | Silent (SNP) | VAF 49/372 reads (13%) | called by muse, mutect2, varscan2
- CDH7 | c.2118C>T p.I706= | Silent (SNP) | VAF 44/239 reads (18%) | catalogued as rs142733191, COSV59888127; called by muse, mutect2, varscan2
- CUBN | c.5523G>T p.T1841= | Silent (SNP) | VAF 18/316 reads (6%) | catalogued as rs767515084, COSV64715543, COSV64717173; called by muse, mutect2
- EXTL3 | c.126C>T p.F42= | Silent (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- FAM186A | c.741C>A p.T247= | Silent (SNP) | VAF 53/309 reads (17%) | called by muse, mutect2, varscan2
- GALNT10 | c.894G>A p.P298= | Silent (SNP) | VAF 4/65 reads (6%) | catalogued as rs1011961773, COSV51728960; called by muse, mutect2
- GPR158 | c.1470C>A p.L490= | Silent (SNP) | VAF 28/430 reads (7%) | catalogued as COSV66272088; called by muse, mutect2
- GRPR | c.345G>T p.L115= | Silent (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- GTF3C3 | c.1752G>A p.R584= | Silent (SNP) | VAF 12/246 reads (5%) | catalogued as COSV55831097; called by muse, mutect2
- HERC2 | c.11070G>A p.K3690= | Silent (SNP) | VAF 11/203 reads (5%) | called by muse, mutect2
- HNRNPCL1 | c.594G>A p.L198= | Silent (SNP) | VAF 14/401 reads (3%) | called by muse, mutect2
- HYDIN | c.289T>C p.L97= | Silent (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- IGLV3-22 | c.30C>A p.L10= | Silent (SNP) | VAF 8/107 reads (7%) | called by muse, mutect2
- KCNA5 | c.1194C>T p.I398= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV52904611; called by muse, mutect2, varscan2
- KIAA0586 | c.3432G>T p.L1144= (on ENST00000619416 / NM_001244190.2; = p.L1083= on NM_014749.5) | Silent (SNP) | VAF 32/254 reads (13%) | called by muse, mutect2, varscan2
- LAMA1 | c.1887G>A p.Q629= | Silent (SNP) | VAF 69/356 reads (19%) | catalogued as rs1303885526; called by muse, mutect2, varscan2
- LOXHD1 | c.1011C>A p.G337= | Silent (SNP) | VAF 39/239 reads (16%) | called by muse, mutect2, varscan2
- MARCO | c.123G>T p.G41= | Silent (SNP) | VAF 32/132 reads (24%) | called by muse, mutect2, varscan2
- MTSS2 | c.729G>A p.E243= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- MUC17 | c.5343C>A p.T1781= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- MYCBPAP | c.1044C>A p.G348= | Silent (SNP) | VAF 32/183 reads (17%) | catalogued as rs375671335; called by muse, mutect2, varscan2
- MYH1 | c.4278G>A p.Q1426= | Silent (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- MYO3B | c.4017T>A p.A1339= | Silent (SNP) | VAF 50/207 reads (24%) | called by muse, mutect2, varscan2
- MYT1 | c.429C>A p.S143= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- NLRP3 | c.228C>A p.I76= | Silent (SNP) | VAF 30/257 reads (12%) | called by muse, mutect2, varscan2
- NPAP1 | c.894C>A p.S298= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV61510828; called by muse, mutect2, varscan2
- OGFR | c.1122G>T p.P374= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as rs377152446; called by muse, mutect2, varscan2
- OR14A2 | c.255C>A p.T85= | Silent (SNP) | VAF 28/215 reads (13%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1716C>T p.G572= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as rs371120832; called by muse, mutect2
- PDGFRB | c.2964C>A p.S988= | Silent (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- PGM5 | c.1425G>A p.K475= | Silent (SNP) | VAF 44/200 reads (22%) | called by muse, mutect2, varscan2
- POMT2 | c.2026T>C p.L676= | Silent (SNP) | VAF 17/187 reads (9%) | called by muse, mutect2, varscan2
- PTHLH | c.333G>A p.V111= | Silent (SNP) | VAF 32/363 reads (9%) | called by muse, mutect2
- PTPRD | c.438T>A p.L146= | Silent (SNP) | VAF 17/353 reads (5%) | called by muse, mutect2
- REEP4 | c.639G>T p.R213= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs776604788; called by muse, mutect2, varscan2
- RYR2 | c.3168G>T p.T1056= | Silent (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2
- SLC51A | c.843G>A p.Q281= | Silent (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- STC1 | c.306G>T p.G102= | Silent (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- TBC1D32 | c.2643A>T p.P881= | Silent (SNP) | VAF 26/276 reads (9%) | called by muse, mutect2, varscan2
- TEX44 | c.159C>T p.S53= | Silent (SNP) | VAF 74/290 reads (26%) | catalogued as rs190453542; called by muse, mutect2, varscan2
- TIAM1 | c.1677G>T p.T559= | Silent (SNP) | VAF 56/393 reads (14%) | catalogued as COSV99731731; called by muse, mutect2, varscan2
- TIE1 | c.6C>A p.V2= | Silent (SNP) | VAF 22/105 reads (21%) | called by muse, mutect2, varscan2
- TNKS | c.3627G>C p.G1209= | Silent (SNP) | VAF 15/245 reads (6%) | called by muse, mutect2
- UNC5C | c.2193T>A p.A731= | Silent (SNP) | VAF 23/240 reads (10%) | catalogued as rs1456794496; called by muse, mutect2
- UROC1 | c.30C>A p.G10= | Silent (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- ZFHX3 | c.2139G>T p.L713= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- ZFHX4 | c.10702C>T p.L3568= | Silent (SNP) | VAF 25/241 reads (10%) | catalogued as COSV50644406; called by muse, mutect2, varscan2
- ZNF318 | c.5007C>T p.S1669= | Silent (SNP) | VAF 26/183 reads (14%) | called by muse, mutect2, varscan2
- AL355390.1 | n.459C>A | RNA (SNP) | VAF 22/312 reads (7%) | called by muse, mutect2
- BDKRB1 | chr14:96268433 G>T | 3'Flank (SNP) | VAF 26/202 reads (13%) | called by muse, mutect2, varscan2
- BRAF | c.-27G>T | 5'UTR (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- C8orf31 | n.726G>A | RNA (SNP) | VAF 11/222 reads (5%) | called by muse, mutect2
- CLCA3P | n.247A>C | RNA (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2
- COL18A1-AS2 | chr21:45405385 C>T | 3'Flank (SNP) | VAF 6/16 reads (38%) | called by muse, varscan2
- ERBIN | c.4057-57G>T | Intron (SNP) | VAF 15/184 reads (8%) | called by muse, mutect2
- FMO6P | n.1681G>T | RNA (SNP) | VAF 25/241 reads (10%) | called by muse, mutect2, varscan2
- MYL3 | chr3:46833192 C>A | 3'Flank (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2
- Metazoa_SRP | chr15:62246567 C>A | 5'Flank (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- NAALADL2 | c.1653+15793A>T | Intron (SNP) | VAF 20/187 reads (11%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.342G>T | RNA (SNP) | VAF 34/636 reads (5%) | catalogued as rs756401841; called by muse, mutect2
- NBPF3 | c.993-9G>T | Intron (SNP) | VAF 48/330 reads (15%) | called by muse, mutect2, varscan2
- NEB | c.11602-15689G>T | Intron (SNP) | VAF 99/999 reads (10%) | called by muse, mutect2, varscan2
- NTNG1 | c.1088-9609G>T | Intron (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- NTRK3 | c.2133+21G>T | Intron (SNP) | VAF 12/253 reads (5%) | called by muse, mutect2
- S1PR3 | c.-252G>T | 5'UTR (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- SCN4B | c.*2414C>A | 3'UTR (SNP) | VAF 58/634 reads (9%) | called by muse, mutect2
- SPIDR | chr8:47260900 C>T | 5'Flank (SNP) | VAF 4/12 reads (33%) | catalogued as rs1478652912; called by muse, varscan2
- TNFRSF14 | c.305-190G>T | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- UBIAD1 | c.*42G>A | 3'UTR (SNP) | VAF 14/211 reads (7%) | called by muse, mutect2
